Somatic mutation profile of tumor specimen MMRF_2690_1_BM_CD138pos (aliquot MMRF_2690_1_BM_CD138pos_T1_KHS5U_L14414) from MMRF case MMRF_2690, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.9 years (18,953 days).
Specimen MMRF_2690_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7da904f-380d-44a6-b537-12e51c0bfc00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2690_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2690_1_PB_WBC_C2_KHS5U_L14415; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0318d8d4-183b-47c9-bdee-aa56533db604

The open-access MAF lists 17 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 3, Intron 3, Missense Mutation 3, Silent 2, Splice Region 1, In Frame Del 1, 3'Flank 1, Splice Site 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHOX2B | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs104893855, CM041818, COSV56930322; ClinVar: risk factor / uncertain significance; called by muse, mutect2, varscan2
- MYO1E | c.3+1G>C p.X1_splice | Splice Site (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2, varscan2
- NUP188 | c.2971C>G p.L991V | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PCNX2 | c.2580G>C p.L860F | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, varscan2
- PCNX2 | c.2505A>C p.R835= | Splice Region (SNP) | VAF 18/44 reads (41%) | called by muse, varscan2
- TBC1D12 | c.642_659del p.A215_G220del | In Frame Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- DAPK1 | c.2877T>C p.C959= | Silent (SNP) | VAF 18/38 reads (47%) | called by mutect2, varscan2
- MEX3C | c.450C>T p.T150= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs1278934982; called by muse, mutect2, varscan2
- CASP9 | c.*723C>T | 3'UTR (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- CGB1 | chr19:49038851 C>T | 5'Flank (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2
- CNTNAP4 | c.-86A>G | 5'UTR (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- GRIA4 | c.1269+1684G>T | Intron (SNP) | VAF 13/190 reads (7%) | called by muse, mutect2
- NAV2 | chr11:20121303 C>T | 3'Flank (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- PIFO | c.390-143A>T | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, varscan2
- RUNDC3A | c.*298dup | 3'UTR (INS) | VAF 20/143 reads (14%) | called by mutect2, pindel, varscan2
- TRPM2 | c.3638-48C>T | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- ZSCAN5C | c.*16T>C | 3'UTR (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2, varscan2
